Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A80L, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A80L-01A (Primary Tumor).

Clinical data

Right pheochromocytoma.

Question: pheo? Radical?

Description material: right adrenal.

**Macroscopy**

Fresh: adrenal gland with a weight of 22 grams and dimensions of 7 x 4 x 2 cm. The adrenal gland is completely encapsulated. At one place a spherical lesion of 3.5 cm. A fragment of the tumor is frozen. Also normal adrenal fragment is frozen.

Cassette 1-2: 2 number of sections of the tumor.

Cassette 3: normal adrenal.

Partially 3b.

Microscopy

Intersected trough lesion with on the edge pre-existing adrenal tissue.

The lesion is moderately sharply defined by a pseudo-capsule and exists partly from groups, partly trabecular located moderately polymorphic cells with occasional Zellballen and areas of hemorrhage. The cells have round oval nuclei with a fine chromatin pattern and prominent nucleolus surrounded by what large granular basophilic cytoplasm. Also a spread of highly polymorphic regions of cells with large hyperchromatic, irregular nuclei with little cytoplasm. No striking mitotic activity, no necrosis. No growth in the peri-adrenal fat. Local suspected vascular invasion. Intersected by normal adrenal showing mild hepatic architecture and construction.

Conclusion

Laparoscopic right adrenalectomy: pheochromocytoma.

Resection borders free.

ICD-O-3
Pheochromocytoma NOS 8700/0
Site: @ Adrenal gland NOS C74.9
Q4 10/17/13

Source: NCI Genomic Data Commons file 7fe86257-02a7-44be-a4f5-6728209d5bf1 (TCGA-WB-A80L.9479D330-6FD6-42C3-927E-D5C525BCBA0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).